Somatic mutation profile of tumor specimen 0DCER2 from CCDI case PBBLSZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Meningioma, NOS; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 17.8 years (6,500 days).
Specimen 0DCER2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c8153d2d-cdc4-47b2-8a26-ee31a97c9d84.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DCEQV (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9f32354e-f071-4acf-a188-af6d3d8ec1ab

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TTN | c.22990C>T p.R7664W (on ENST00000591111; = p.R6737W on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 108/339 reads (32%) | PolyPhen possibly damaging (0.9); catalogued as rs1227497572, COSV60158883; called by muse, varscan2
- DPP9 | c.2244+308C>T | Intron (SNP) | VAF 254/670 reads (38%) | catalogued as rs973301747; called by muse, varscan2
